Surgical pathology report (de-identified scan), TCGA case TCGA-CV-7101, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-7101-01A (Primary Tumor).

[page 1 of 2]
**** Case imported from legacy computer system. The format of this report does not match the original case. ****

**** For cases prior to the section "SPECIMEN" may have been added. ****

SUPPLEMENTAL REPORT

COMMENT:

This supplemental report is issued to provide results following decalcification of additional sections.

Sections of the ossified thyroid cartilage adjacent to the tumor show the tumor to invade completely through the thyroid cartilage into the anterior soft tissue, where there is perineural invasion in proximity to the right lobe of the thyroid.

Entire report and diagnosis completed by:

DIAGNOSIS

(A) ANTERIOR COMMISSURE, BIOPSY:

FRAGMENTS OF MODERATELY-DIFFERENTIATED SQUAMOUS CARCINOMA.

(B) POSTERIOR WALL OF ESOPHAGUS, BIOPSY:

Squamous mucosa, no tumor present.

(C) LARYNX, TOTAL LARYNGECTOMY AND NEAR TOTAL THYROIDECTOMY:

INVASIVE MODERATELY-DIFFERENTIATED SQUAMOUS CARCINOMA (2.4 CM) OF RIGHT TRUE VOCAL CORD WITH RIGHT SUPRAGLOTTIC (SUBMUCOSA OF FALSE CORD) AND SUBGLOTTIC EXTENSION.

TUMOR CROSSES MIDLINE TO INVOLVE LEFT ANTERIOR VOCAL CORD.

TUMOR INVADES RIGHT PARAGLOTTIC SPACE. (SEE COMMENT)

NO LYMPHATIC/VASCULAR INVASION IDENTIFIED.

MARGINS FREE OF TUMOR.

THYROID, NO TUMOR PRESENT.

[page 2 of 2]
Entire report and diagnosis completed by: [REDACTED]

COMMENT

Sections of thyroid cartilage will be examined following decalcification, and a supplemental report will follow.

GROSS DESCRIPTION

(A) ANTERIOR COMMISSURE - A fragmented portion of pink-tan soft tissue (0.8 x 0.3 x 0.2 cm). Submitted entirely in one cassette for frozen section. [REDACTED]

*FS/DX: ANTERIOR COMMISSURE. FRAGMENTS OF MODERATELY DIFFERENTIATED SQUAMOUS CELL CARCINOMA. [REDACTED]

(B) POSTERIOR WALL OF ESOPHAGUS - A minute pink-tan mucosal lined soft tissue fragment measuring 0.5 x 0.3 x 0.2 cm. Bisected and submitted in toto for frozen section as B. [REDACTED]

*FS/DX: POST WALL ESOPHAGUS SQUAMOUS MUCOSA, NO TUMOR PRESENT. [REDACTED]

(C) TOTAL LARYNGECTOMY AND NEAR TOTAL THYROIDECTOMY - A larynx, hyoid bone, and anterior soft tissue (9.2 x 6.5 x 6.0 cm) with subtotal thyroidectomy (4.5 x 3.5 x 1.5 cm).

There is a flat, ulcerated tumor of the mucosa of the right true cord (2.4 x 1.5 x 1.2 cm). The tumor extends 1.7 cm below the right ventricle. There is ulceration which crosses the anterior commissure (to an extent of 0.4 cm across the midline). There is necrotic tumor in the paraglottic space on the right. The tumor is 2.7 cm away from the inferior (tracheal) margin of resection. Margins are grossly free of tumor. Thyroid gland and soft tissue are unremarkable. Representative portions of tumor are submitted for flow cytometry and investigational studies.

SECTION CODE: C1-C4, mucosal margin submitted from right piriform sinus around epiglottis to left piriform sinus (frozen section); C5, inferior tracheal margin; C6, thyroid; C7, posterior commissure; C8, anterior commissure; C9, right aryepiglottic fold nearest tumor; C10, epiglottis; C11, right posterior glottis and paraglottic space; C12, right mid glottis and paraglottic space; C13, right anterior glottis; C14, left anterior glottis; C15, left mid glottis and periglottic space; C16, left posterior glottis, para-glottic space; C17, pre-epiglottic space; C18, one possible lymph node from pre-epiglottic soft tissue. [REDACTED]

*FS/DX: TOTAL LARYNGECTOMY AND NEAR TOTAL THYROIDECTOMY. MUCOSAL MARGINS, SQUAMOUS MUCOSA, NO TUMOR PRESENT. [REDACTED]

SNOMED CODES

M-80703 T-24100

Source: NCI Genomic Data Commons file 34eab2fa-c1cb-4eca-a498-1e44079c5cec (TCGA-CV-7101.B83617E3-EB33-4307-80EB-329F56461917.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).